Somatic mutation profile of tumor specimen C3L-06019-01 (aliquot CPT0359050006) from CPTAC case C3L-06019, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.2 years (27,482 days).
Specimen C3L-06019-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fd7cc4b-9a83-4a9e-9d99-9a41a97ebd24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06019-31 (Blood Derived Normal), aliquot CPT0360460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfde59e1-805f-4dfd-8a6b-f1502bc65c0c

The open-access MAF lists 49 somatic variants for this specimen: 34 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 29, Silent 15, Nonsense Mutation 3, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AASDHPPT | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.676); catalogued as rs761620246, COSV53789640; called by muse, mutect2, varscan2
- ADCY1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 91/426 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs768415059, COSV52029771; called by muse, mutect2, varscan2
- CPD | c.410A>T p.N137I | Missense Mutation (SNP) | VAF 151/546 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56711679; called by muse, mutect2, varscan2
- CTNND2 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58884726; called by muse, mutect2, varscan2
- EIF2S2 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66621409; called by muse, mutect2, varscan2
- GABRA4 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 85/378 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51931450; called by muse, mutect2, varscan2
- MAPK6 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 115/514 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55929260; called by muse, mutect2, varscan2
- MYO18A | c.5473C>T p.R1825W | Missense Mutation (SNP) | VAF 134/426 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752123909, COSV62868500; called by muse, mutect2, varscan2
- NLRP11 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV64087848; called by muse, mutect2, varscan2
- NRG1 | c.1856C>T p.S619L (on ENST00000405005 / NM_013964.5; = p.S624L on NM_013956.5) | Missense Mutation (SNP) | VAF 127/532 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776135585, COSV99828588, COSV99829522; called by muse, mutect2, varscan2
- PROKR2 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 141/422 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370738961, CM1010043; called by muse, mutect2, varscan2
- RIPK4 | c.1559C>T p.S520F (on ENST00000352483; = p.S472F on NM_020639.3) | Missense Mutation (SNP) | VAF 108/430 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.443); catalogued as rs772009598; called by muse, mutect2, varscan2
- STC1 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 94/462 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1307541175, COSV51689304; called by muse, varscan2
- ANK3 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF10 | c.3340C>A p.H1114N (on ENST00000398564; = p.H1089N on NM_014629.4) | Missense Mutation (SNP) | VAF 166/674 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- B4GALT5 | c.737dup p.Y246* | Nonsense Mutation (INS) | VAF 91/415 reads (22%) | called by mutect2, pindel, varscan2
- BTBD9 | c.665T>G p.M222R | Missense Mutation (SNP) | VAF 99/698 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- CENPJ | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 77/271 reads (28%) | called by muse, mutect2, varscan2
- DCAF8 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DVL3 | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 104/340 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- IMP3 | c.-11_9del | Translation Start Site (DEL) | VAF 35/183 reads (19%) | called by mutect2, pindel, varscan2
- IRF3 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 150/533 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- KANK4 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 189/664 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MYO15B | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 166/492 reads (34%) | SIFT tolerated, low confidence (0.59); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- NARS2 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- OR10A5 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 118/422 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.215); called by muse, varscan2
- PAPPA2 | c.3406G>T p.G1136* | Nonsense Mutation (SNP) | VAF 109/351 reads (31%) | called by muse, mutect2, varscan2
- PLA2G4D | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 143/648 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- PPAT | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SMCR8 | c.104dup p.F37Lfs*7 | Frame Shift Ins (INS) | VAF 88/271 reads (32%) | called by mutect2, pindel, varscan2
- VEGFC | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZNF804A | c.1451G>T p.C484F | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF891 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 130/409 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- AC099489.1 | c.2220G>A p.R740= | Silent (SNP) | VAF 106/309 reads (34%) | called by muse, mutect2, varscan2
- ANK3 | c.1323C>T p.A441= | Silent (SNP) | VAF 58/194 reads (30%) | catalogued as COSV55059291; called by muse, mutect2, varscan2
- BICD2 | c.2439C>T p.A813= | Silent (SNP) | VAF 134/325 reads (41%) | catalogued as rs755522406, COSV63548504; called by muse, mutect2, varscan2
- ELP1 | c.1923C>T p.I641= | Silent (SNP) | VAF 89/308 reads (29%) | catalogued as COSV65900290; called by muse, mutect2, varscan2
- FOXF1 | c.936G>A p.P312= | Silent (SNP) | VAF 115/457 reads (25%) | catalogued as CD135720; called by muse, mutect2, varscan2
- FOXP4 | c.1173C>T p.S391= | Silent (SNP) | VAF 281/726 reads (39%) | called by muse, mutect2, varscan2
- GDPD5 | c.1623G>C p.R541= | Silent (SNP) | VAF 101/412 reads (25%) | called by muse, mutect2, varscan2
- GRB10 | c.1701G>A p.L567= (on ENST00000398812; = p.L521= on NM_001001549.3) | Silent (SNP) | VAF 105/493 reads (21%) | called by muse, mutect2, varscan2
- KCNA5 | c.1746C>T p.P582= | Silent (SNP) | VAF 138/623 reads (22%) | called by muse, mutect2, varscan2
- LGI3 | c.609C>T p.F203= | Silent (SNP) | VAF 150/585 reads (26%) | called by muse, mutect2, varscan2
- LIMS2 | c.978G>A p.L326= (on ENST00000355119 / NM_001161403.3; = p.L350= on NM_017980.4) | Silent (SNP) | VAF 101/360 reads (28%) | called by muse, mutect2, varscan2
- NLRP5 | c.1828C>T p.L610= | Silent (SNP) | VAF 133/438 reads (30%) | called by muse, mutect2, varscan2
- PHRF1 | c.4674G>A p.E1558= (on ENST00000264555 / NM_001286581.2; = p.E1557= on NM_020901.4) | Silent (SNP) | VAF 85/346 reads (25%) | called by muse, mutect2, varscan2
- RNF165 | c.795C>A p.T265= | Silent (SNP) | VAF 51/279 reads (18%) | called by muse, mutect2, varscan2
- SETX | c.4155C>T p.D1385= | Silent (SNP) | VAF 83/352 reads (24%) | catalogued as rs759387462, COSV56378452; called by muse, mutect2, varscan2
